Somatic mutation profile of tumor specimen C3L-04539-01 (aliquot CPT0264350006) from CPTAC case C3L-04539, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 75.8 years (27,684 days).
Specimen C3L-04539-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54883a2d-ddac-4334-abd6-bca2c1927d7d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04539-31 (Blood Derived Normal), aliquot CPT0265800002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/696c7856-8c91-48b7-98d0-9ff72268a535

The open-access MAF lists 81 somatic variants for this specimen: 54 protein-altering or splice-affecting, 19 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 19, Nonsense Mutation 4, Intron 4, RNA 2, 5'UTR 1, 3'Flank 1, Frame Shift Del 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3019G>C p.G1007R | Missense Mutation (SNP) | VAF 22/55 reads (40%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.797); catalogued as COSV55882140; called by muse, mutect2
- AC127029.3 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 174/420 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); catalogued as rs780941513, COSV60111419; called by muse, mutect2, varscan2
- CACNA1C | c.959C>T p.T320M | Missense Mutation (SNP) | VAF 100/230 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs377737331; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CASP14 | c.680C>T p.T227M | Missense Mutation (SNP) | VAF 70/312 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.159); catalogued as rs149050628; called by muse, mutect2, varscan2
- COL1A2 | c.2488C>T p.R830* | Nonsense Mutation (SNP) | VAF 164/646 reads (25%) | catalogued as rs990076088, COSV99798977; called by muse, mutect2, varscan2
- CPAMD8 | c.3737C>T p.A1246V (on ENST00000651564; = p.A1199V on NM_015692.5) | Missense Mutation (SNP) | VAF 90/318 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as rs766475107; called by muse, mutect2, varscan2
- FAM78B | c.509C>T p.T170M | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.49); catalogued as rs759808562, COSV57978754; called by muse, mutect2, varscan2
- FBN2 | c.2150G>A p.R717H | Missense Mutation (SNP) | VAF 86/214 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs773896695, COSV52491204; called by muse, mutect2, varscan2
- FBXW10 | c.2956G>A p.V986M | Missense Mutation (SNP) | VAF 156/214 reads (73%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs1391274748; called by muse, varscan2
- FER1L5 | c.3026C>T p.A1009V (on ENST00000623019; = p.A1016V on NM_001293083.2) | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as COSV67606494; called by muse, mutect2, varscan2
- GABRA2 | c.509T>A p.L170* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV62917727; called by muse, mutect2, varscan2
- GRIN2D | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.031); catalogued as rs956514019; called by muse, mutect2, varscan2
- HS3ST3A1 | c.761C>T p.T254M | Missense Mutation (SNP) | VAF 138/515 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52372831; called by muse, mutect2, varscan2
- IL36A | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 89/233 reads (38%) | catalogued as rs780011138, COSV52082815; called by muse, varscan2
- JPH1 | c.547G>A p.A183T | Missense Mutation (SNP) | VAF 53/271 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs775236412, COSV60612115; called by muse, mutect2, varscan2
- MTO1 | c.1465C>T p.R489C (on ENST00000370300 / NM_133645.3; = p.R464C on NM_012123.4) | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1459252796, COSV64773727; called by muse, mutect2, varscan2
- MYOCD | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764293311, COSV58506565; called by muse, mutect2, varscan2
- OPLAH | c.1811G>A p.R604H | Missense Mutation (SNP) | VAF 148/372 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.28); catalogued as rs200399200; called by muse, mutect2, varscan2
- OR2T12 | c.256G>A p.G86R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.741); catalogued as rs1409983118, COSV58779975; called by mutect2, varscan2
- PCDHGB3 | c.1397C>T p.P466L | Missense Mutation (SNP) | VAF 118/267 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as rs758674133, COSV53898031; called by muse, mutect2, varscan2
- PDHA2 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs754242583, COSV54780630; called by muse, mutect2, varscan2
- PIK3CG | c.2515C>T p.R839C | Missense Mutation (SNP) | VAF 39/111 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774448553, COSV63245228; called by muse, mutect2, varscan2
- RNF223 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 65/196 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs773521509, COSV69251393; called by muse, mutect2, varscan2
- SCNN1G | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 115/273 reads (42%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.751); catalogued as rs752038199, COSV55597592, COSV55599455; called by muse, mutect2, varscan2
- SLC1A6 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 133/555 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV55667543; called by muse, mutect2, varscan2
- SLCO1B1 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as rs201861991; called by muse, mutect2, varscan2
- SNED1 | c.1636G>A p.D546N | Missense Mutation (SNP) | VAF 102/234 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60031726; called by muse, mutect2, varscan2
- SPATA2L | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs771688020, COSV57045883; called by muse, mutect2, varscan2
- STAT1 | c.1288C>T p.L430F | Missense Mutation (SNP) | VAF 81/213 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.757); catalogued as COSV63117176; called by muse, mutect2, varscan2
- SYNE1 | c.16381G>T p.D5461Y (on ENST00000367255 / NM_182961.4; = p.D5390Y on NM_033071.3) | Missense Mutation (SNP) | VAF 31/164 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV99583989; called by muse, mutect2, varscan2
- TBX20 | c.1258C>T p.R420* | Nonsense Mutation (SNP) | VAF 46/164 reads (28%) | catalogued as rs377570351; called by muse, mutect2, varscan2
- TEK | c.3226C>T p.R1076W | Missense Mutation (SNP) | VAF 72/93 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757379347, COSV66227449; called by muse, mutect2, varscan2
- TENM3 | c.7873C>T p.R2625W | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV69308587; called by muse, mutect2, varscan2
- A1CF | c.1206G>T p.L402F (on ENST00000373993 / NM_138932.2; = p.L394F on NM_014576.4) | Missense Mutation (SNP) | VAF 89/142 reads (63%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ARHGAP24 | c.969C>G p.S323R (on ENST00000395184 / NM_001025616.3; = p.S230R on NM_031305.3) | Missense Mutation (SNP) | VAF 75/185 reads (41%) | SIFT tolerated (0.54); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- CD163L1 | c.2610C>G p.H870Q | Missense Mutation (SNP) | VAF 105/258 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CTNND1 | c.449del p.T150Nfs*85 | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | called by mutect2, pindel, varscan2
- FAM83B | c.1456C>T p.H486Y | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KIAA1755 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- LAMB3 | c.894C>A p.N298K | Missense Mutation (SNP) | VAF 130/335 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MTA1 | c.191-4dup | Splice Region (INS) | VAF 34/136 reads (25%) | called by mutect2, pindel, varscan2
- NANOG | c.565C>A p.P189T | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OLR1 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 53/163 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- OR11H1 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.421); called by mutect2, varscan2
- OR51B2 | c.269T>C p.I90T | Missense Mutation (SNP) | VAF 6/137 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.127); called by muse, mutect2
- OR6C1 | c.619T>A p.F207I | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- OR6K3 | c.568A>T p.I190F (on ENST00000368146; = p.I174F on NM_001005327.2) | Missense Mutation (SNP) | VAF 89/218 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PHLDB3 | c.968T>C p.L323P | Missense Mutation (SNP) | VAF 51/162 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- TNRC6B | c.3074G>C p.G1025A (on ENST00000454349 / NM_001162501.2; = p.G972A on NM_015088.3) | Missense Mutation (SNP) | VAF 65/99 reads (66%) | SIFT tolerated (1); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- TPRX1 | c.31-1G>A p.X11_splice | Splice Site (SNP) | VAF 33/146 reads (23%) | called by muse, mutect2, varscan2
- TTN | c.69214G>T p.V23072F (on ENST00000591111; = p.V15648F on NM_003319.4) | Missense Mutation (SNP) | VAF 31/78 reads (40%) | PolyPhen possibly damaging (0.565); called by muse, mutect2, varscan2
- UGT2B7 | c.103C>A p.H35N | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ZKSCAN8 | c.872G>A p.G291E | Missense Mutation (SNP) | VAF 133/315 reads (42%) | SIFT tolerated (0.96); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF558 | c.967A>T p.N323Y | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- ABCB5 | c.2949G>A p.S983= (on ENST00000404938 / NM_001163941.2; = p.S538= on NM_178559.6) | Silent (SNP) | VAF 34/145 reads (23%) | catalogued as rs369991802, COSV99329228; called by muse, mutect2, varscan2
- ADAMTS20 | c.3039G>A p.T1013= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as rs1226793000; called by muse, mutect2, varscan2
- ATG2A | c.1635G>A p.T545= | Silent (SNP) | VAF 100/273 reads (37%) | catalogued as rs202089842; called by muse, mutect2, varscan2
- DNAH11 | c.3108C>A p.T1036= | Silent (SNP) | VAF 41/179 reads (23%) | called by muse, mutect2, varscan2
- EPHA10 | c.2265A>G p.A755= | Silent (SNP) | VAF 78/210 reads (37%) | called by muse, mutect2, varscan2
- FA2H | c.621G>A p.T207= | Silent (SNP) | VAF 54/129 reads (42%) | catalogued as rs779856022; called by muse, mutect2, varscan2
- FOXP4 | c.1602C>T p.A534= (on ENST00000307972 / NM_001012426.1; = p.A521= on NM_138457.3) | Silent (SNP) | VAF 16/280 reads (6%) | catalogued as rs371009599; called by muse, mutect2
- GRM5 | c.1332C>A p.T444= | Silent (SNP) | VAF 100/259 reads (39%) | called by muse, mutect2, varscan2
- GUCY2D | c.1191C>T p.D397= | Silent (SNP) | VAF 138/345 reads (40%) | catalogued as rs756210907, COSV54697853; called by muse, mutect2, varscan2
- IQCN | c.3294C>T p.S1098= | Silent (SNP) | VAF 40/162 reads (25%) | catalogued as rs1056388430; called by muse, mutect2, varscan2
- ITGAL | c.99G>A p.A33= | Silent (SNP) | VAF 72/173 reads (42%) | called by muse, mutect2, varscan2
- KRT26 | c.84C>T p.F28= | Silent (SNP) | VAF 123/288 reads (43%) | catalogued as COSV100053255; called by muse, mutect2, varscan2
- MCRIP1 | c.174C>T p.G58= | Silent (SNP) | VAF 85/260 reads (33%) | catalogued as rs1431900608; called by muse, mutect2, varscan2
- NLRP2 | c.87G>T p.L29= | Silent (SNP) | VAF 192/636 reads (30%) | called by muse, mutect2, varscan2
- OTOP3 | c.1113G>A p.A371= | Silent (SNP) | VAF 108/240 reads (45%) | catalogued as rs368567485; called by muse, mutect2, varscan2
- SIGLECL1 | c.13C>T p.L5= | Silent (SNP) | VAF 64/150 reads (43%) | called by muse, mutect2, varscan2
- SLCO3A1 | c.369G>A p.S123= | Silent (SNP) | VAF 162/387 reads (42%) | catalogued as rs1027026668; called by muse, mutect2, varscan2
- SULT6B1 | c.756T>C p.A252= (on ENST00000535679 / NM_001367551.1; = p.A214= on NM_001032377.2) | Silent (SNP) | VAF 9/105 reads (9%) | called by muse, mutect2
- TMEM151A | c.807G>A p.S269= | Silent (SNP) | VAF 79/208 reads (38%) | catalogued as COSV59174396; called by muse, mutect2, varscan2
- CCDC40 | c.1562+574G>A | Intron (SNP) | VAF 56/129 reads (43%) | catalogued as rs781128358; called by muse, mutect2, varscan2
- CLEC5A | c.209-28C>T | Intron (SNP) | VAF 51/188 reads (27%) | catalogued as rs782465228; called by muse, mutect2, varscan2
- FLT4 | c.2762-18C>T | Intron (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- GATA4 | chr8:11761736 del T | 3'Flank (DEL) | VAF 55/131 reads (42%) | called by mutect2, pindel, varscan2
- PTCH2 | c.-19G>T | 5'UTR (SNP) | VAF 37/65 reads (57%) | called by muse, mutect2, varscan2
- RGL3 | c.371+59C>T | Intron (SNP) | VAF 31/97 reads (32%) | called by muse, mutect2, varscan2
- RPS26P15 | n.125G>A | RNA (SNP) | VAF 103/467 reads (22%) | catalogued as rs370812259; called by muse, mutect2, varscan2
- TRIM51BP | n.1035T>A | RNA (SNP) | VAF 48/407 reads (12%) | called by muse, mutect2, varscan2
